CGCI case BLGSP-71-08-00030 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3703e3e9-1f3a-445e-9538-d924014c822d

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 7 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Ovary; Classification of tumor: primary; Age at diagnosis: 7.4 years (2,706 days); Year of diagnosis: 2013; Method of diagnosis: Core Biopsy; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 173 days; Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Endemic; Max tumor bulk site: Ovary; Sites of involvement: Ovary, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS; Surgery, NOS, for recurrent disease.

Follow-up (3 entries)
- Days to follow up: 0 days; Karnofsky performance status: 50; ECOG performance status: 3.
- Days to follow up: 143 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Pelvis, NOS; Days to recurrence: 143 days; Evidence of recurrence type: Positive Biomarker(s).
- Days to follow up: 173 days; Disease response: Tumor Free.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.

Other clinical attributes
- Day 0: Weight: 24.2 kg; Height: 130 cm; BMI: 14.3.

Biospecimens (3 samples)
- Sample BLGSP-71-08-00030-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Ovary; Preservation method: Frozen; Days to sample procurement: 0 days; Method of sample procurement: Needle Biopsy; Tissue collection type: Retrospective.
- Sample BLGSP-71-08-00030-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-08-00030-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen; Days to sample procurement: 0 days; Method of sample procurement: Blood Draw; Tissue collection type: Retrospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Lost to follow-up: No; New tumor event diagnosis indicator: Yes.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 1; Lymph nodes examined: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: No Known Nodal Involvement.
- New tumor event: New tumor event type: Locoregional Recurrence; New tumor event site other: pelvic masses Lt+Rt; New tumor event surgery: No; New tumor event pharmaceutical treatment: Yes.
